Somatic mutation profile of tumor specimen TCGA-24-2035-01A (aliquot TCGA-24-2035-01A-01W-0722-08) from TCGA case TCGA-24-2035, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 65.3 years (23,855 days).
Specimen TCGA-24-2035-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2efa1339-b64b-4206-8a69-bd2fafc830cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-2035-10A (Blood Derived Normal), aliquot TCGA-24-2035-10A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/022a9534-695d-4513-9707-bfd6187e3598

The open-access MAF lists 107 somatic variants for this specimen: 87 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 19, Nonsense Mutation 8, In Frame Del 3, Splice Site 2, Frame Shift Del 2, Frame Shift Ins 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.5129del p.G1710Efs*4 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs1135401829; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACP6 | c.706A>G p.K236E | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.615); catalogued as COSV65077291; called by muse, mutect2, varscan2
- ADAMTS3 | c.1218G>T p.M406I | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as COSV99710364, COSV99712378; called by muse, mutect2
- AKAP9 | c.11155C>G p.H3719D (on ENST00000359028; = p.H3695D on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV100662067; called by muse, mutect2, varscan2
- ALG10B | c.747G>A p.M249I | Missense Mutation (SNP) | VAF 43/243 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV58143728, COSV58145283; called by muse, mutect2, varscan2
- APC | c.6704G>T p.G2235V | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99966012; called by muse, mutect2
- C21orf91 | c.400C>G p.Q134E | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV53033136; called by muse, mutect2, varscan2
- CAMSAP1 | c.2800C>T p.H934Y | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.261); catalogued as COSV56724277; called by muse, mutect2, varscan2
- CARS1 | c.2072T>G p.F691C | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99542204; called by muse, mutect2, varscan2
- CFAP77 | c.796C>A p.P266T | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV58012989; called by muse, mutect2, varscan2
- CLEC18B | c.319G>T p.G107C | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1474275453, COSV100375774; called by mutect2, varscan2
- CLHC1 | c.467C>G p.T156S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.057); catalogued as COSV63427123; called by muse, mutect2, varscan2
- CLINT1 | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs746859496, COSV51626145; called by muse, mutect2, varscan2
- COL14A1 | c.2225T>C p.V742A | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1451835275, COSV52859060; called by muse, mutect2, varscan2
- COL6A6 | c.3994G>T p.A1332S | Missense Mutation (SNP) | VAF 13/230 reads (6%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.877); catalogued as rs998688546, COSV100649968; called by muse, mutect2
- COLEC10 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV60521057, COSV60521810; called by muse, mutect2, varscan2
- CSMD3 | c.5653A>T p.R1885* (on ENST00000297405 / NM_001363185.1; = p.R1781* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 90/174 reads (52%) | catalogued as COSV52224943, COSV52240584; called by muse, mutect2, varscan2
- CXCR6 | c.665G>T p.G222V | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99945302; called by muse, mutect2
- DCTN2 | c.820G>A p.A274T (on ENST00000548249 / NM_001261413.2; = p.A279T on NM_006400.4) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV63075360; called by muse, mutect2, varscan2
- DNMT1 | c.1567A>G p.T523A | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.088); catalogued as COSV61580759; called by muse, mutect2, varscan2
- ECE1 | c.425G>A p.G142D | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV99941492; called by muse, mutect2, varscan2
- EDC4 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.453); catalogued as COSV54646000; called by muse, mutect2, varscan2
- EDEM1 | c.1340T>G p.V447G | Missense Mutation (SNP) | VAF 283/457 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56582523, COSV99849213; called by muse, mutect2, varscan2
- EEF1G | c.1163C>A p.P388Q | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as COSV100240190; called by muse, mutect2, varscan2
- EHD3 | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV100434644; called by muse, mutect2
- EXOC2 | c.1386G>T p.Q462H | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as COSV57867913; called by muse, mutect2, varscan2
- GPBP1 | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV53312631; called by muse, mutect2, varscan2
- HKDC1 | c.2432C>G p.T811R | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs556646884, COSV63577828, COSV63578930; called by muse, mutect2, varscan2
- HS3ST3A1 | c.706A>C p.T236P | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52376474; called by muse, mutect2, varscan2
- KIF13B | c.3809G>A p.R1270K | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101580546, COSV72954750; called by muse, mutect2, varscan2
- KRT4 | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as COSV53408320; called by muse, mutect2, varscan2
- LAMC2 | c.1891G>T p.E631* | Nonsense Mutation (SNP) | VAF 12/195 reads (6%) | catalogued as COSV99917185; called by muse, mutect2
- LAMC3 | c.3875C>A p.T1292N | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV62654701; called by muse, mutect2, varscan2
- LPAR6 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57299486; called by muse, mutect2, varscan2
- LRIG1 | c.2951C>A p.A984D | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV56242627; called by muse, mutect2, varscan2
- LYN | c.109A>G p.T37A | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.624); catalogued as rs1426951318, COSV101571211; called by muse, mutect2, varscan2
- MACF1 | c.15355A>T p.M5119L (on ENST00000372915; = p.M3052L on NM_012090.5) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as COSV57128991; called by muse, mutect2, varscan2
- MAP3K19 | c.1058G>T p.G353V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV59638811, COSV59640258; called by muse, mutect2, varscan2
- MKI67 | c.6923A>G p.E2308G | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.6); catalogued as rs200297314, COSV100896289; called by muse, mutect2, varscan2
- MROH7 | c.3631C>T p.R1211W | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs375795723; called by muse, mutect2, varscan2
- MUC16 | c.5198C>A p.S1733Y | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.106); catalogued as COSV67476011, COSV67477614; called by muse, mutect2, varscan2
- MUC17 | c.5545C>G p.P1849A | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as COSV60279259, COSV60293442; called by muse, mutect2, varscan2
- MYCBPAP | c.758G>C p.R253P | Missense Mutation (SNP) | VAF 35/39 reads (90%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV60408708, COSV60409269; called by muse, mutect2, varscan2
- MYLK4 | c.1121A>G p.K374R | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV51144340; called by muse, varscan2
- MYRIP | c.171G>T p.Q57H | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.429); catalogued as COSV56872994; called by muse, mutect2, varscan2
- NEU3 | c.1309C>T p.H437Y | Missense Mutation (SNP) | VAF 68/227 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53637195; called by muse, mutect2, varscan2
- NOS1 | c.2974G>A p.V992I | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV100500182; called by mutect2, varscan2
- NPAT | c.1228C>G p.Q410E | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as COSV53719096; called by muse, mutect2, varscan2
- NUBP1 | c.434G>C p.R145T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51594462; called by muse, mutect2, varscan2
- NUGGC | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1271161380, COSV100429039; called by muse, mutect2, varscan2
- NXPE3 | c.1234A>G p.I412V | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as rs1264956930, COSV56290620; called by muse, mutect2, varscan2
- PDLIM4 | c.341C>A p.T114K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.86); PolyPhen benign (0.006); catalogued as COSV53804531; called by muse, mutect2, varscan2
- POU2F2 | c.886C>T p.R296W (on ENST00000526816 / NM_001207025.3; = p.R280W on NM_002698.5) | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV60764616; called by muse, mutect2, varscan2
- PTK2 | c.1276C>T p.R426* | Nonsense Mutation (SNP) | VAF 63/228 reads (28%) | catalogued as rs1247173286, COSV61788072; called by muse, mutect2, varscan2
- RAD51AP2 | c.357dup p.S120Lfs*5 | Frame Shift Ins (INS) | VAF 5/47 reads (11%) | catalogued as rs750569378; called by pindel, varscan2
- RETREG3 | c.1142A>G p.E381G | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99518796; called by muse, mutect2
- RS1 | c.586T>G p.S196A | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV66106872; called by muse, mutect2, varscan2
- RTKN | c.1221G>A p.W407* (on ENST00000272430 / NM_001015055.2; = p.W394* on NM_033046.2) | Nonsense Mutation (SNP) | VAF 12/254 reads (5%) | catalogued as COSV99269400; called by muse, mutect2
- RUSC1 | c.1459C>G p.L487V (on ENST00000368352 / NM_001105203.2; = p.L18V on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV52740845; called by muse, mutect2, varscan2
- SH2D3C | c.584C>A p.S195* (on ENST00000314830 / NM_170600.3; = p.S38* on NM_005489.4) | Nonsense Mutation (SNP) | VAF 9/113 reads (8%) | catalogued as COSV100136550; called by muse, mutect2
- SLC12A5 | c.982C>A p.L328M (on ENST00000454036 / NM_001134771.2; = p.L305M on NM_020708.5) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as COSV99715534; called by muse, varscan2
- SNTG1 | c.347G>A p.C116Y | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV52427421; called by muse, mutect2, varscan2
- SRPK2 | c.945G>C p.Q315H | Missense Mutation (SNP) | VAF 90/202 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.948); catalogued as rs372166705, COSV100624407; called by muse, mutect2, varscan2
- STC1 | c.716T>A p.I239N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV99282383; called by muse, mutect2, varscan2
- SULT1E1 | c.591+1G>A p.X197_splice | Splice Site (SNP) | VAF 17/64 reads (27%) | catalogued as COSV56947565; called by muse, mutect2, varscan2
- TAF4 | c.3151A>G p.T1051A | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.191); catalogued as COSV53339289; called by muse, mutect2
- TFAP2D | c.876G>C p.L292F | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV50415269, COSV50429099; called by muse, mutect2, varscan2
- TIAL1 | c.326C>T p.T109I | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV64843365; called by muse, mutect2, varscan2
- TINAG | c.1051T>G p.C351G | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52511453; called by muse, mutect2, varscan2
- TJP3 | c.1061-1G>T p.X354_splice | Splice Site (SNP) | VAF 92/191 reads (48%) | catalogued as COSV53663710; called by muse, mutect2, varscan2
- TLL1 | c.1762C>A p.Q588K | Missense Mutation (SNP) | VAF 87/457 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99286509; called by muse, mutect2, varscan2
- TMEM44 | c.1042G>T p.E348* (on ENST00000392432 / NM_001166305.2; = p.E301* on NM_138399.5) | Nonsense Mutation (SNP) | VAF 62/385 reads (16%) | catalogued as COSV99861615; called by muse, mutect2, varscan2
- TMEM63A | c.814C>G p.L272V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV100834296; called by muse, mutect2, varscan2
- TNPO3 | c.497G>T p.R166L | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99602557; called by muse, mutect2
- TTLL4 | c.2621G>C p.S874T | Missense Mutation (SNP) | VAF 94/195 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as COSV99293111; called by muse, mutect2, varscan2
- TTN | c.8728G>T p.V2910F (on ENST00000591111; = p.V2864F on NM_003319.4) | Missense Mutation (SNP) | VAF 39/445 reads (9%) | PolyPhen probably damaging (0.967); catalogued as COSV100589575; called by muse, mutect2
- USP19 | c.3237G>T p.W1079C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100025914; called by muse, mutect2, varscan2
- ZHX2 | c.1802G>C p.G601A | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV100073754, COSV58714442; called by muse, mutect2, varscan2
- ZNF135 | c.1540C>T p.R514* (on ENST00000313434 / NM_001289401.2; = p.R526* on NM_003436.4) | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as rs773683116, COSV57883395; called by muse, mutect2, varscan2
- ZNF287 | c.1912C>T p.H638Y | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101209341; called by muse, mutect2, varscan2
- ZNF560 | c.448G>T p.G150C | Missense Mutation (SNP) | VAF 66/812 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752102698, COSV56869156; called by muse, mutect2
- OR52N2 | c.158_193del p.H53_F64del | In Frame Del (DEL) | VAF 186/317 reads (59%) | called by mutect2, pindel
- OR8G2P | c.573C>A p.S191R | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PCLO | c.10435_10449del p.Q3479_D3483del | In Frame Del (DEL) | VAF 8/64 reads (13%) | called by mutect2, pindel, varscan2
- SLC22A3 | c.534G>A p.R178= | Splice Region (SNP) | VAF 171/284 reads (60%) | called by muse, varscan2
- TP53 | c.945_946del p.Q317Afs*19 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | called by pindel, varscan2
- TRPM2 | c.1371_1388del p.K457_W462del | In Frame Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, pindel, varscan2
- ATP7B | c.4290G>A p.L1430= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as rs1484552869, COSV54439072; called by muse, mutect2, varscan2
- AXIN1 | c.2118G>A p.Q706= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV51989114; called by muse, mutect2, varscan2
- CNTFR | c.501C>A p.R167= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV63634121; called by muse, mutect2, varscan2
- COL4A6 | c.4437G>A p.V1479= | Silent (SNP) | VAF 36/61 reads (59%) | catalogued as COSV57870323; called by muse, mutect2, varscan2
- CTCF | c.1746C>T p.G582= | Silent (SNP) | VAF 16/139 reads (12%) | catalogued as rs1262338132, COSV50496605; called by muse, mutect2, varscan2
- DGKB | c.1386A>G p.L462= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs779230777, COSV51764059; called by muse, mutect2, varscan2
- DNAH12 | c.240T>C p.D80= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV60857473; called by muse, mutect2, varscan2
- ETS2 | c.390G>A p.Q130= | Silent (SNP) | VAF 81/246 reads (33%) | catalogued as COSV100711219; called by muse, mutect2, varscan2
- FRMPD4 | c.3945C>T p.P1315= | Silent (SNP) | VAF 52/207 reads (25%) | catalogued as COSV101042358; called by muse, mutect2, varscan2
- INTS3 | c.855C>T p.F285= | Silent (SNP) | VAF 105/426 reads (25%) | catalogued as COSV59679021; called by muse, mutect2, varscan2
- KEAP1 | c.135C>A p.S45= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as COSV50307193; called by muse, mutect2, varscan2
- LMOD3 | c.1680G>A p.A560= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs377046368, COSV56235651; called by muse, mutect2, varscan2
- PCDHAC1 | c.2676C>T p.S892= | Silent (SNP) | VAF 47/109 reads (43%) | catalogued as rs199624636, COSV53856932; called by muse, mutect2, varscan2
- PIK3CA | c.528A>G p.E176= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs765535078, COSV55944969; called by muse, mutect2, varscan2
- PPP1R7 | c.531T>C p.S177= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs1204067730, COSV52145654; called by muse, mutect2, varscan2
- PRPF6 | c.1176T>A p.V392= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV53873193; called by muse, mutect2, varscan2
- SF3B2 | c.33A>C p.A11= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs746881973, COSV59426975; called by muse, mutect2, varscan2
- SLC6A9 | c.1869C>T p.C623= (on ENST00000360584 / NM_201649.4; = p.C569= on NM_006934.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs1375030381, COSV62211169; called by muse, mutect2, varscan2
- WHRN | c.2446C>T p.L816= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV54332163; called by muse, mutect2, varscan2
- MIR376A2 | n.14_56del | RNA (DEL) | VAF 18/50 reads (36%) | called by mutect2, pindel
